Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67R, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67R-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number

Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

- Source of Specimen
- A. RIGHT PELVIC LYMPH NODES NFS-
- B. RIGHT PELVIC LYMPH NODE FS-
- C. MIDDLE LOBE OF PROSTATE-
- D. PROSTATE SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODES NFS-
NO CARCINOMA SEEN IN FOUR LYMPH NODES (0/4).
- B. RIGHT PELVIC LYMPH NODE FS-
SEE PART A FOR DIAGNOSIS.
- C. MIDDLE LOBE OF PROSTATE-
PROSTATIC HYPERPLASIA. NO CARCINOMA SEEN.
- D. PROSTATE SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE.

TUMOR SITE: BILATERAL, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 47 GRAMS. SIZE: 5 x 5 x 4 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 3 = 7/10.

SEVERITY IN EXTENT OF TUMOR: 2 / 5.

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): PRESENT, 2.1 CM IN SIZE.

Final

ICD-O-3

path
Adenocarcinoma NOS 8140/3
cuff
Adenocarcinoma, acinar 8140/3
Site: Prostate NOS C61.9
JED 5/9/13

Prepared for

Criteria	met 4/22/13	Yes	No
HIKAA Discrepancy			

[page 2 of 5]
TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: AT LEAST pT2c (SEE COMMENT), pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

POSITIVE INKED MARGINS: RIGHT PROSTATE, SEE COMMENT.

OTHER MARGINS ARE CLEAR.

COMMENT: THE POSITIVE MARGIN APPEARS TO BE DISRUPTED BY AN IATROGENIC INCISION. THERE IS NO EXTRAPROSTATIC INVASION SEEN ELSEWHERE. FURTHER CLINICAL CORRELATION IS NEEDED.

Signature

(Case signed)

Signed Others

Frozen Section

A. RIGHT PELVIC LYMPH NODES: 4 LYMPH NODES WITH NTS.

FS performed by

(Frozen Section Signed

Case Clinical Information

PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "right pelvic lymph node non-FS" are multiple yellow-brown fibroadipose tissue fragments measuring 4.5 x 4 x 2 cm. Fragment lymph nodes are grossly identified, measuring in aggregate 2 x 2 x 1 cm. The specimen is entirely submitted in A1-A4.

B. Received in formalin labeled with the patient's name and "right pelvic lymph node FS" are four yellow-tan frozen section tissue fragments measuring 1.7 x 0.5 cm. Entirely submitted in B1-B2.

C. Received in formalin labeled with the patient's name and

Prepared for

[page 3 of 5]
"middle lobe of prostate" is a gray-tan, firm tissue fragment measuring 1 x 0.8 cm. Trisected and entirely submitted in C1. D. Received in formalin labeled with the patient's name and number, and "prostate seminal vesicle" is a radical prostatectomy specimen which includes a 47-gram prostate gland with attached seminal vesicles and vas deferens. The prostate gland measures 5 x 5 x 4 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 2 x 1 cm. The right vas measures 1.5 x 0.4 cm. The left vas measures 1 x 0.4 cm. The left seminal vesicle measures 1.5 x 1 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen, and then sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The right seminal vesicle and vas deferentia are grossly unremarkable. The left seminal vesicle shows a gray-tan adjacent nodule measuring 0.5 x 0.5 cm. The specimen is represented as follows: inferior prostate to demonstrate apical margin submitted entirely anterior to posterior in D1-D6; bladder resection margin is perpendicularly sectioned and submitted in D7-D8; complete section of mid gland anterior D9-D10; posterior D11-D12; complete section of upper third of gland, anterior D13-D14; posterior D15-D16; remainder of the posterior gland entirely submitted in D17-D22; right seminal vesicle and vas deferens D23; left seminal vesicle, vas deferens, and the nodule adjacent to the seminal vesicle entirely submitted D24-D26. Also in the same container are two blocks for research, entirely submitted.

Physicians

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.2
H&E X1

Prepared for _____

[page 4 of 5]
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.4
H&E X1
D. AA ROUTINE H&E X1 BLOCK.5
H&E X1
D. AA ROUTINE H&E X1 BLOCK.6
H&E X1
D. AA ROUTINE H&E X1 BLOCK.7
H&E X1
D. AA ROUTINE H&E X1 BLOCK.8
H&E X1
D. AA ROUTINE H&E X1 BLOCK.9
H&E X1
D. AA ROUTINE H&E X1 BLOCK.10
H&E X1
D. AA ROUTINE H&E X1 BLOCK.11
H&E X1
D. AA ROUTINE H&E X1 BLOCK.12
H&E X1
D. AA ROUTINE H&E X1 BLOCK.13
H&E X1
D. AA ROUTINE H&E X1 BLOCK.14
H&E X1
D. AA ROUTINE H&E X1 BLOCK.15
H&E X1
D. AA ROUTINE H&E X1 BLOCK.16
H&E X1
D. AA ROUTINE H&E X1 BLOCK.17
H&E X1
D. AA ROUTINE H&E X1 BLOCK.18
H&E X1
D. AA ROUTINE H&E X1 BLOCK.19
H&E X1
D. AA ROUTINE H&E X1 BLOCK.20
H&E X1
D. AA ROUTINE H&E X1 BLOCK.21
H&E X1
D. AA ROUTINE H&E X1 BLOCK.22
H&E X1
D. AA ROUTINE H&E X1 BLOCK.23
H&E X1
D. AA ROUTINE H&E X1 BLOCK.24

Prepared fo.

[page 5 of 5]
H&E X1

D. AA ROUTINE H&E X1 BLOCK.25

H&E X1

D. AA ROUTINE H&E X1 BLOCK.26

H&E X1

Prepared for

Source: NCI Genomic Data Commons file e2f944a0-ae75-4a29-8635-068625583da5 (TCGA-J4-A67R.EAFE4CB1-BB7F-4D26-851D-49ECE5A73750.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).